Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q3, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q3-01A (Primary Tumor).

[page 1 of 3]
Accession #: _____
Date of Procedure: _____
Date of Receipt: _____
Date of Report: _____
Account #: _____
Billing Type: INPATIENT
Additional Copy to: _____

Ref. Source: _____

Clinical Diagnosis & History:

year old female with left thyroid nodule status post FNA positive for papillary thyroid CA.

Specimens Submitted:

- 1: Total thyroidectomy
- 2: Delphian node
- 3: Additional Delphian node
- 4: Right paratracheal tissue

DIAGNOSIS:

1. Total thyroidectomy:

Tumor Type:
Papillary carcinoma, tall cell variant

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Other Tumor Features:
Marked stromal reaction

Tumor Location:
Left lobe

Tumor Size:
Greatest diameter is 0.8 cm.

Tumor Encapsulation:
None Identified

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Invades: perithyroidal soft tissue and focally skeletal muscle

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

Adenoma(s) (away from the carcinoma):
Not identified

Non-Neoplastic Thyroid:

ICD-0-3

carcinoma, papillary, tall cell variant
8344/3

Site: thyroid, nos C73.9

w
8/31/11

[page 2 of 3]
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis
Parathyroid Glands:
Not identified

Lymph Nodes:
Perinodal (extracapsular) extension not identified
One of two lymph nodes are positive for metastatic thyroid carcinoma (1/2). The involved lymph node measures 0.55 cm and the metastatic focus measures <0.1 cm

2. Delphian node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

3. Additional Delphian node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2

4. Right paratracheal tissue:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	THYROG	
	IMM RECUT	
	NEG CONT	

Gross Description:

1. The specimen is received fresh, labeled "total thyroidectomy" and consists of a total thyroidectomy, measuring as follows: right lobe 5.0 x 2.9 x 0.6 cm; the left lobe 4.6 x 2.3 x 0.7 cm and the isthmus 1.0 x 0.3 x 1.3cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a single nodule in the left lobe of the thyroid, in the upper pole, 0.7 x 0.8 x 0.6cm, with a white-yellow firm cut surface. Sections through the remaining tissue reveal red tan and beefy parenchyma. TPS is submitted. The entire thyroid is submitted.

Summary of sections:
N - Left thyroid, upper lobe, nodule, entirely submitted
RL - right lobe, remainder
LL - left lobe, remainder

[page 3 of 3]
IS – isthmus

MD

2. The specimen is received in formalin labeled "Delphian node" and consists of a 0.8 x 0.5 x 0.4 cm possible lymph node. Entirely submitted.

Summary of sections

LN- possible lymph node

MD

3. The specimen is received in formalin labeled "Additional Delphian node" and consists of a 1 x 0.5 x 0.4 cm possible lymph node. Entirely submitted.

Summary of sections

LN- possible lymph node

MD

4. The specimen is received in formalin labeled "Right paratracheal tissue" and consists of a 2x 1 x 0.4 cm fragment of fibro-adipose tissue with two 0.3 and 0.4 cm lymph nodes. Specimen entirely submitted.

Summary of sections

LN- lymph nodes and fibro-adipose tissue

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
4	LL	4
2	N	2
5	RL	5

Part 2: Delphian node

Block	Sect. Site	PCs
1	LN	1

Part 3: Additional Delphian node

Block	Sect. Site	PCs
1	LN	1

Part 4: Right paratracheal tissue

Block	Sect. Site	PCs
1	LN	1

Source: NCI Genomic Data Commons file ecf15120-9665-4158-ae59-5a79dd76efa4 (TCGA-DJ-A2Q3.A65C7D99-30AE-46C3-AFA3-691C0EB0D43C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).